Somatic mutation profile of cancer-model specimen HCM-WCMC-0946-C34-85A (3D Organoid; aliquot HCM-WCMC-0946-C34-85A-01D-A905-36), derived from the primary tumor of HCMI case HCM-WCMC-0946-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 79.9 years (29,167 days).
Specimen HCM-WCMC-0946-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39e24e76-9035-4f32-b166-a5fc7e5be0c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0946-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0946-C34-10A-01D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc9b174d-dcca-4065-b2d0-feced3e77557

The open-access MAF lists 50 somatic variants for this specimen: 43 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 34, Silent 7, Nonsense Mutation 5, Splice Site 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 136/304 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 113/264 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCE1 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1282696739, COSV56846407; called by muse, mutect2
- ALDH1L1 | c.2599G>A p.D867N | Missense Mutation (SNP) | VAF 49/524 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775642396; called by muse, mutect2
- CA7 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 137/309 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs1317831546; called by muse, mutect2, varscan2
- DNAH7 | c.2040A>C p.Q680H | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.423); catalogued as COSV100415700; called by muse, mutect2, varscan2
- ENTPD7 | c.586T>A p.L196I | Missense Mutation (SNP) | VAF 137/293 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs1164546473; called by muse, mutect2, varscan2
- FBN1 | c.1905C>G p.Y635* | Nonsense Mutation (SNP) | VAF 133/307 reads (43%) | catalogued as CM095635; called by muse, mutect2, varscan2
- FOXP2 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 160/341 reads (47%) | catalogued as rs1474090446; called by muse, mutect2, varscan2
- GALNT18 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 177/379 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs951723727, COSV57159478; called by muse, mutect2, varscan2
- GMPPA | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 200/448 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs373966812; called by muse, mutect2, varscan2
- GPR107 | c.1652A>G p.D551G (on ENST00000372406 / NM_001136557.2; = p.D503G on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/356 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs151019150; called by muse, mutect2, varscan2
- GYS2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs781309842, COSV53924698; called by muse, mutect2
- HYDIN | c.8468C>T p.T2823M | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs1420432999, COSV99992969; called by mutect2, varscan2
- IGSF9 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 93/414 reads (22%) | catalogued as rs950811935, COSV63639516; called by muse, mutect2, varscan2
- KCNQ2 | c.2119G>A p.A707T (on ENST00000359125 / NM_172107.4; = p.A679T on NM_004518.6) | Missense Mutation (SNP) | VAF 243/804 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs543477138, COSV60544464; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYH6 | c.3583C>T p.R1195C | Missense Mutation (SNP) | VAF 178/674 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769756450, COSV100676327; ClinVar: uncertain significance; called by muse, varscan2
- NTRK3 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 105/352 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs149623569, COSV100446683; called by muse, mutect2, varscan2
- NUP205 | c.5716C>T p.R1906C | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1430838133; called by muse, mutect2
- PROS1 | c.1429G>T p.V477F | Missense Mutation (SNP) | VAF 151/326 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV67775412; called by muse, mutect2, varscan2
- TMEM125 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 70/543 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.03); catalogued as rs761203348; called by muse, mutect2, varscan2
- TMEM130 | c.1249C>T p.R417C (on ENST00000416379 / NM_001134450.2; = p.R405C on NM_152913.3) | Missense Mutation (SNP) | VAF 221/415 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782136245, COSV59559438; called by muse, mutect2, varscan2
- VWA2 | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 166/325 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs764526217; called by muse, mutect2, varscan2
- WFDC1 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 71/449 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141305670; called by muse, mutect2, varscan2
- ATAT1 | c.558_563dup p.E187_G188dup | In Frame Ins (INS) | VAF 201/451 reads (45%) | called by mutect2, pindel, varscan2
- BCOR | c.3463dup p.D1155Gfs*13 | Frame Shift Ins (INS) | VAF 335/791 reads (42%) | called by mutect2, pindel, varscan2
- CALY | c.246+1G>C p.X82_splice | Splice Site (SNP) | VAF 302/589 reads (51%) | called by muse, mutect2, varscan2
- EBF2 | c.1214T>G p.V405G | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.354); called by muse, mutect2
- IMPDH2 | c.882C>G p.Y294* | Nonsense Mutation (SNP) | VAF 54/312 reads (17%) | called by muse, mutect2, varscan2
- ITPRID1 | c.1415C>A p.S472* | Nonsense Mutation (SNP) | VAF 174/364 reads (48%) | called by muse, mutect2, varscan2
- MSRA | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 179/379 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MYH8 | c.2746A>C p.I916L | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- NIBAN1 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 151/309 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR4C15 | c.979T>C p.F327L (on ENST00000314644; = p.F273L on NM_001001920.2) | Missense Mutation (SNP) | VAF 175/367 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PPP3CA | c.1438A>G p.N480D | Missense Mutation (SNP) | VAF 193/389 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QPCT | c.453C>A p.N151K | Missense Mutation (SNP) | VAF 206/425 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- RBBP6 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 109/245 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SETDB2 | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 170/328 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHC3 | c.881T>A p.I294N | Missense Mutation (SNP) | VAF 70/287 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIMP4 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- TP53BP1 | c.2821+1G>T p.X941_splice | Splice Site (SNP) | VAF 67/140 reads (48%) | called by muse, mutect2, varscan2
- TRIO | c.5614C>G p.P1872A | Missense Mutation (SNP) | VAF 287/582 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTPA | c.491A>T p.Q164L | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.029); called by muse, mutect2
- C11orf53 | c.693G>C p.P231= | Silent (SNP) | VAF 221/488 reads (45%) | called by muse, mutect2, varscan2
- CUX2 | c.2406C>T p.S802= | Silent (SNP) | VAF 380/780 reads (49%) | catalogued as rs1206055312; called by muse, varscan2
- LEUTX | c.249T>C p.H83= | Silent (SNP) | VAF 220/416 reads (53%) | called by muse, mutect2, varscan2
- LTB | c.342G>C p.T114= | Silent (SNP) | VAF 377/776 reads (49%) | called by muse, mutect2, varscan2
- MYT1L | c.2082G>A p.A694= | Silent (SNP) | VAF 274/557 reads (49%) | called by muse, mutect2, varscan2
- OR6F1 | c.738C>T p.T246= | Silent (SNP) | VAF 130/443 reads (29%) | catalogued as rs372082158, COSV57467135, COSV57467283; called by muse, mutect2, varscan2
- RASA4B | c.745C>T p.L249= | Silent (SNP) | VAF 68/394 reads (17%) | called by muse, mutect2, varscan2
